Somatic mutation profile of tumor specimen HTMCP-03-06-02025-01A (aliquot HTMCP-03-06-02025-01A-01D-4427) from CGCI case HTMCP-03-06-02025, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 63.6 years (23,231 days).
Specimen HTMCP-03-06-02025-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f538e7f8-723d-45c7-a2be-7d6889e1979f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02025-10A (Blood Derived Normal), aliquot HTMCP-03-06-02025-10A-01D-4427; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3750dfe-ae77-4f37-a1cb-b39f48495eb5

The open-access MAF lists 105 somatic variants for this specimen: 75 protein-altering or splice-affecting, 22 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 22, Nonsense Mutation 6, Intron 4, 5'UTR 2, Splice Site 2, RNA 2, Translation Start Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C12orf43 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs1176572996, COSV56566313, COSV56566816; called by muse, mutect2, varscan2
- C6orf118 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs375226918, COSV100025322; called by muse, mutect2, varscan2
- CECR2 | c.1684C>T p.R562W (on ENST00000342247 / NM_001290047.2; = p.R379W on NM_001290046.1) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs768986689, COSV52840831; called by muse, mutect2, varscan2
- CHGB | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV66760758; called by muse, mutect2
- CNST | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 12/92 reads (13%) | catalogued as rs753311239, COSV100830062; called by muse, mutect2, varscan2
- COL11A1 | c.3622G>A p.E1208K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV62174353; called by muse, mutect2, varscan2
- CPAMD8 | c.1990G>A p.A664T (on ENST00000651564; = p.A617T on NM_015692.5) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs568970755, COSV52236816; called by mutect2, varscan2
- FBXW7 | c.2077G>A p.E693K (on ENST00000281708 / NM_001349798.2; = p.E613K on NM_018315.5) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55901729; called by muse, mutect2
- FOXG1 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57396226; called by muse, mutect2, varscan2
- FRYL | c.2699G>A p.S900N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.4); catalogued as rs1409777743; called by muse, mutect2, varscan2
- IVL | c.102G>T p.M34I | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.023); catalogued as COSV64215662; called by muse, mutect2, varscan2
- JAK2 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV101074934; called by muse, mutect2
- KCNH1 | c.901C>G p.L301V | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); catalogued as COSV99657709; called by muse, mutect2, varscan2
- KDM4B | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV50214073; called by muse, mutect2, varscan2
- KIDINS220 | c.3541G>C p.E1181Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs1314890393; called by muse, mutect2, varscan2
- LRRC7 | c.4399C>T p.R1467W (on ENST00000651989 / NM_001370785.2; = p.R1387W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs755856495, COSV50412001; called by muse, mutect2, varscan2
- LYST | c.6694G>A p.G2232R | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.909); catalogued as rs748659198, CM162296; called by muse, varscan2
- NAA15 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1015535318, COSV56722217; called by muse, mutect2
- NF2 | c.71dup p.R25Efs*24 | Frame Shift Ins (INS) | VAF 4/16 reads (25%) | catalogued as CI087778; called by mutect2, varscan2
- OVCH2 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766400158; called by muse, mutect2, varscan2
- PALB2 | c.2922G>C p.K974N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV55165022; called by muse, mutect2, varscan2
- PCDHB2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.111); catalogued as rs1355068524; called by muse, mutect2, varscan2
- RB1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57325375, COSV99926730; called by muse, mutect2, varscan2
- RFX7 | c.2449C>G p.L817V (on ENST00000559447 / NM_001368074.1; = p.L914V on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV100429378; called by mutect2, varscan2
- RUNX2 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61838635; called by muse, mutect2
- SORCS1 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as rs376036249, COSV53892494; called by muse, mutect2, varscan2
- TGFBR2 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV55457199; called by muse, varscan2
- TP53BP1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as rs1049302691; called by muse, mutect2
- TTN | c.99463G>A p.E33155K (on ENST00000591111; = p.E25731K on NM_003319.4) | Missense Mutation (SNP) | VAF 16/117 reads (14%) | PolyPhen benign (0.359); catalogued as COSV60242402; called by muse, mutect2, varscan2
- USP6NL | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1179053039; called by muse, mutect2, varscan2
- XIRP2 | c.7039C>T p.H2347Y (on ENST00000628543; = p.H2522Y on NM_152381.6) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV54683852, COSV54698097; called by muse, mutect2, varscan2
- ZNF560 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV56872600; called by muse, mutect2, varscan2
- AHNAK | c.17493G>C p.K5831N | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ARHGAP5 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/117 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CARMIL3 | c.2653G>A p.G885S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CDC42BPB | c.2488G>A p.D830N | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CDK16 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP74 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CNNM1 | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CR1 | c.5482C>G p.Q1828E | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.061); called by muse, mutect2
- CSMD1 | c.3450C>A p.F1150L (on ENST00000520002; = p.F1149L on NM_033225.6) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CTSH | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by mutect2, varscan2
- DACT1 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- DISP1 | c.4294G>C p.E1432Q | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH6 | c.9231G>C p.L3077F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DST | c.21258G>A p.M7086I (on ENST00000361203 / NM_001374722.1; = p.M4783I on NM_015548.5) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DST | c.19087G>C p.E6363Q (on ENST00000361203 / NM_001374722.1; = p.E4060Q on NM_015548.5) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- FAM81B | c.1285G>C p.D429H | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.16); called by muse, mutect2
- FBXW7 | c.1927G>A p.D643N (on ENST00000281708 / NM_001349798.2; = p.D563N on NM_018315.5) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMN2 | c.1936C>A p.Q646K | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXP1 | c.510+2T>G p.X170_splice | Splice Site (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- GPRASP1 | c.2314G>C p.E772Q | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- GRIK2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- GUCY1A2 | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- HSPG2 | c.1505G>T p.R502L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- KIAA1586 | c.586A>G p.K196E | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2
- KIAA2026 | c.3802G>C p.E1268Q | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYH15 | c.3394G>C p.E1132Q | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MYOM1 | c.3865-1G>A p.X1289_splice | Splice Site (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- MYRIP | c.1552del p.H518Tfs*34 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by pindel, varscan2
- NASP | c.2296C>G p.Q766E | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAB3GAP2 | c.2076G>C p.E692D | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RARG | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNF43 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2
- SVIL | c.1300G>C p.G434R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF9 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMTC3 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTC14 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- TTF2 | c.493C>G p.Q165E | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- TXNDC16 | c.1864C>T p.L622F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.34); called by muse, mutect2
- VPS16 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- ZNF160 | c.1686G>C p.E562D | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2
- ZNF286A | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- ZNF286A | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- AKAP13 | c.2202C>T p.F734= | Silent (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- DNAAF2 | c.1380C>T p.N460= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- FAT4 | c.6265C>T p.L2089= | Silent (SNP) | VAF 28/161 reads (17%) | called by muse, mutect2, varscan2
- GNPTAB | c.2805C>T p.L935= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV54780020; called by muse, mutect2
- GOLGA8B | c.234G>A p.L78= | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2
- KDM3B | c.4209G>A p.K1403= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- KLF15 | c.429G>A p.E143= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- MAGI1 | c.267C>T p.V89= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- NBPF12 | c.813C>T p.S271= | Silent (SNP) | VAF 9/169 reads (5%) | catalogued as rs1165721371; called by muse, mutect2
- NCOA6 | c.327G>A p.R109= | Silent (SNP) | VAF 21/147 reads (14%) | called by muse, mutect2, varscan2
- PCNX1 | c.6579C>T p.S2193= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- POT1 | c.1398C>G p.L466= | Silent (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- SYNGAP1 | c.1767C>T p.I589= | Silent (SNP) | VAF 4/33 reads (12%) | called by mutect2, varscan2
- TBL1XR1 | c.528C>G p.A176= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV61790583; called by muse, mutect2, varscan2
- TEP1 | c.45C>T p.L15= | Silent (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- TEX14 | c.945C>G p.L315= (on ENST00000240361 / NM_001201457.2; = p.L309= on NM_031272.5) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV53616981; called by muse, mutect2, varscan2
- THSD7B | c.477C>T p.C159= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV55659569, COSV55664345; called by muse, mutect2, varscan2
- TRPC4AP | c.1668G>A p.L556= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- TUBB8 | c.183C>A p.P61= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV104400229; called by muse, mutect2, varscan2
- ZNF302 | c.885C>T p.L295= (on ENST00000627982; = p.L216= on NM_018443.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- ZNF799 | c.1800C>T p.L600= | Silent (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- ZNF827 | c.2616G>A p.V872= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs377386498; called by muse, mutect2, varscan2
- ARHGEF4 | c.-459C>T | 5'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+2389G>A | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- HBS1L | c.430+2554G>A | Intron (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- MUC19 | n.9075C>G | RNA (SNP) | VAF 31/247 reads (13%) | called by muse, mutect2, varscan2
- MUC19 | n.9669G>C | RNA (SNP) | VAF 36/285 reads (13%) | called by muse, mutect2, varscan2
- NFAT5 | c.73+2146G>C | Intron (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2, varscan2
- PAX2 | c.-50G>C | 5'UTR (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.10360+5470G>A | Intron (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
